Gene-level copy-number profile of tumor specimen TCGA-55-8614-01A from TCGA case TCGA-55-8614, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 76.5 years (27,924 days).
Specimen TCGA-55-8614-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.de1365ba-8058-4d35-a640-f77e2e1d5a5e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-8614-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6cb0f163-41a1-4105-9a68-1dec4aff7729

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 10,686; copy number 3: 13,605; copy number 4: 20,010; copy number 5: 3,225; copy number 6: 3,642; copy number 7: 3,366; copy number 8: 4,087; copy number 9: 333; copy number 11: 240; copy number 12: 475; copy number 15: 88; copy number 24: 4; copy number 29: 13; copy number 34: 36; copy number 54: 3; copy number 59: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-8614-01A-11D-2389-01): tumor purity 0.32, ploidy 4.05, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,196 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–50,846,519, 715 genes, copy number 11–12 (within-gene range 1–12) (broad region; genes not listed).
- chr8:37,326,575–40,897,833, 88 genes, copy number 15–29 (within-gene range 8–29) (broad region; genes not listed).
- chr11:9,778,667–10,294,219, 1 gene, copy number 9 (within-gene range 2–9): SBF2.
- chr11:9,982,753–10,908,972, 21 genes, copy number 9: AC011092.3, AC100763.1, AC080023.2, AC080023.1, ADM, AMPD3, RNU6ATAC33P, MTRNR2L8, MIR4485, RNF141, IRAG1-AS1, LYVE1, IRAG1, Y_RNA, CTR9, EIF4G2, SNORD97, AC116535.1, ZBED5, ZBED5-AS1, AC069360.1.
- chr11:12,030,875–14,364,506, 43 genes, copy number 34–59: LINC02547, AC124276.1, AC124276.2, MICAL2, MIR6124, AC079329.1, AC025300.1, PARVA, AC009806.1, AC107881.1, TEAD1, AC013549.3, AC013549.4, AC013549.2, AC013549.1, LINC00958, RASSF10-DT, RASSF10, AC013762.1, AC022878.1, ARNTL, RN7SKP151, BTBD10, AC021269.3, AC021269.1, AC021269.2, PTH, HMGN2P36, FAR1, FAR1-IT1, RPL39P26, Y_RNA, CENPUP1, AC013828.1, LINC02548, AC027779.1, LINC02545, RNA5SP331, LINC02683, SPON1, RNA5SP332, SPON1-AS1, RRAS2.
- chr20:35,626,031–48,136,844, 328 genes, copy number 9–15 (within-gene range 6–15) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
